Somatic mutation profile of tumor specimen ALCH-B2OZ-TTP1-A (aliquot ALCH-B2OZ-TTP1-A-2-0-D-A777-36) from ALCHEMIST case ALCH-B2OZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,077 days).
Specimen ALCH-B2OZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c70f709-4c5a-4c61-8a10-c40b1a83f1e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2OZ-NB1-A (Blood Derived Normal), aliquot ALCH-B2OZ-NB1-A-1-0-D-A777-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a392fbc-9901-4d2c-b5e1-e45d0646fa29

The open-access MAF lists 427 somatic variants for this specimen: 292 protein-altering or splice-affecting, 81 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 251, Silent 81, Intron 25, Nonsense Mutation 23, RNA 12, 5'Flank 7, Splice Site 7, Frame Shift Del 6, 3'UTR 5, 5'UTR 4, Splice Region 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/602 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- PRPS1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs180177152, CM100185, COSV65054574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALPK2 | c.1817C>A p.T606N | Missense Mutation (SNP) | VAF 73/522 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs777477577; called by muse, mutect2, varscan2
- ANKRD30A | c.2694del p.N899Mfs*5 (on ENST00000611781; = p.N843Mfs*5 on NM_052997.2) | Frame Shift Del (DEL) | VAF 48/258 reads (19%) | catalogued as COSV64605230; called by mutect2, varscan2
- AP5Z1 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 53/246 reads (22%) | catalogued as COSV62243327; called by muse, mutect2, varscan2
- APBA2 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 176/1100 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV68789393; called by muse, mutect2, varscan2
- APMAP | c.940G>T p.G314W | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551862951, COSV54174242; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 42/260 reads (16%) | catalogued as rs758608743; called by mutect2, varscan2
- ASB15 | c.727G>T p.G243W | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51924325; called by muse, mutect2, varscan2
- BEX1 | c.316C>G p.R106G | Missense Mutation (SNP) | VAF 106/333 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as COSV65580771; called by muse, varscan2
- BPIFB4 | c.1263del p.M422Cfs*10 | Frame Shift Del (DEL) | VAF 81/595 reads (14%) | catalogued as COSV64951142; called by mutect2, pindel, varscan2
- CCDC74A | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 72/382 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99723493; called by muse, mutect2, varscan2
- CCNL2 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 140/1034 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.933); catalogued as COSV61224545; called by muse, mutect2, varscan2
- CDH2 | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 96/585 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1277644544; called by muse, mutect2, varscan2
- CNTN5 | c.1216C>A p.P406T | Missense Mutation (SNP) | VAF 73/499 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.186); catalogued as COSV54276690; called by muse, mutect2, varscan2
- COL9A3 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 64/393 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777612158; called by muse, mutect2, varscan2
- CSN3 | c.365del p.P122Qfs*8 | Frame Shift Del (DEL) | VAF 86/639 reads (13%) | catalogued as rs762617305; called by mutect2, pindel, varscan2
- DCAF12L2 | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63582911; called by muse, mutect2, varscan2
- DNLZ | c.405G>C p.Q135H | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV52518132; called by muse, mutect2, varscan2
- DOCK9 | c.395G>A p.G132E (on ENST00000376460 / NM_001366676.2; = p.G133E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.169); catalogued as rs867009890; called by muse, mutect2, varscan2
- EPHB6 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 126/722 reads (17%) | catalogued as COSV101235958; called by muse, mutect2, varscan2
- ERICH3 | c.2515G>A p.A839T | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.135); catalogued as rs200840954, COSV58604339; called by muse, mutect2, varscan2
- FAM83F | c.1236G>T p.K412N | Missense Mutation (SNP) | VAF 106/682 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV61000506; called by muse, mutect2, varscan2
- FBLN2 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs966993314; called by muse, mutect2, varscan2
- FBXO4 | c.1074G>T p.L358= | Splice Region (SNP) | VAF 15/119 reads (13%) | catalogued as COSV55853612; called by muse, mutect2, varscan2
- FKBP15 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99439143; called by muse, mutect2, varscan2
- FOXI1 | c.595C>A p.L199M | Missense Mutation (SNP) | VAF 105/736 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100089276; called by muse, mutect2, varscan2
- GABRA6 | c.347C>A p.T116N | Missense Mutation (SNP) | VAF 117/729 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780224018, COSV50893282; called by muse, mutect2, varscan2
- GLG1 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs776803868; called by muse, mutect2, varscan2
- GOLGA8M | c.283C>G p.Q95E | Missense Mutation (SNP) | VAF 62/405 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1447087845; called by mutect2, varscan2
- GP2 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 53/349 reads (15%) | catalogued as COSV56892929; called by muse, mutect2, varscan2
- GPR148 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as rs376533302; called by muse, mutect2, varscan2
- GRID2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56221538, COSV99946399; called by muse, mutect2, varscan2
- GTSE1 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 104/694 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); catalogued as rs765598902; called by muse, mutect2, varscan2
- H2BC1 | c.302G>C p.R101P | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51238563; called by muse, mutect2, varscan2
- HTR3A | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 64/336 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100248542; called by muse, mutect2, varscan2
- IGKV1D-42 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327483563; called by muse, varscan2
- IGKV2-30 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 122/931 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.227); catalogued as rs760160093; called by muse, mutect2, varscan2
- IRF9 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.467); catalogued as rs765783196; called by muse, mutect2, varscan2
- JPH4 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 131/785 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV62508293; called by muse, mutect2, varscan2
- KIF1A | c.779C>A p.A260D | Missense Mutation (SNP) | VAF 74/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57491467; called by muse, mutect2, varscan2
- KIF7 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1263045856; called by muse, mutect2, varscan2
- KIR3DL2 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 91/442 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54390378; called by muse, mutect2, varscan2
- KIRREL2 | c.429C>A p.N143K | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52879377; called by muse, mutect2, varscan2
- KMT2D | c.6889C>T p.P2297S | Missense Mutation (SNP) | VAF 39/527 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs748334191, COSV56452254; called by muse, mutect2
- LAMA1 | c.2319G>C p.L773F | Missense Mutation (SNP) | VAF 126/767 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV67544563; called by muse, mutect2, varscan2
- LRP1B | c.5960G>T p.R1987L | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67264252; called by muse, varscan2
- MUC16 | c.8254C>T p.P2752S | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101201785; called by muse, mutect2, varscan2
- MYLK4 | c.78G>T p.Q26H | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1428984001; called by muse, mutect2, varscan2
- MZF1 | c.2048G>T p.C683F | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53040648; called by muse, mutect2, varscan2
- NCR1 | c.252C>A p.Y84* | Nonsense Mutation (SNP) | VAF 91/668 reads (14%) | catalogued as rs772234312; called by muse, mutect2
- NRXN1 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1404175088, COSV68022267; called by muse, mutect2, varscan2
- NSG2 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57460009; called by muse, mutect2, varscan2
- OPN1SW | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 103/838 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.975); catalogued as rs1217564642, CM074971; called by muse, mutect2, varscan2
- OR10A7 | c.231G>C p.M77I | Missense Mutation (SNP) | VAF 131/715 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs368066439; called by muse, mutect2, varscan2
- OR10Q1 | c.178C>G p.R60G | Missense Mutation (SNP) | VAF 78/515 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as COSV57470266; called by muse, mutect2, varscan2
- OR2T33 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 67/531 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778820081, COSV100531971, COSV58815594, COSV58817591; called by muse, mutect2, varscan2
- OTOP1 | c.1352C>G p.P451R | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.552); catalogued as COSV99587285; called by muse, mutect2, varscan2
- PCDHA2 | c.2195G>T p.R732L | Missense Mutation (SNP) | VAF 134/790 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); catalogued as rs781899428, COSV65364468; called by muse, mutect2, varscan2
- PHLPP1 | c.4813G>T p.G1605C | Missense Mutation (SNP) | VAF 63/381 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV53023252; called by muse, mutect2, varscan2
- PLD5 | c.1576G>T p.D526Y (on ENST00000442594; = p.D464Y on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/540 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100138660; called by muse, mutect2, varscan2
- PRIM2 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67295268; called by muse, mutect2, varscan2
- PTCHD3 | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV71257114; called by muse, mutect2, varscan2
- RASAL3 | c.1388C>A p.A463E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs765698882; called by muse, mutect2, varscan2
- RELN | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.994); catalogued as rs1352208816; called by muse, mutect2, varscan2
- RGS9BP | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1170446485; called by muse, mutect2, varscan2
- RIMS2 | c.1146G>T p.R382S (on ENST00000666250 / NM_001348490.2; = p.R190S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.816); catalogued as rs184923024; called by muse, mutect2, varscan2
- RSPH9 | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 63/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64521956; called by muse, mutect2, varscan2
- SERPINB3 | c.979G>T p.G327* | Nonsense Mutation (SNP) | VAF 44/293 reads (15%) | catalogued as COSV52189758; called by muse, mutect2, varscan2
- SLC15A3 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1259106294; called by muse, mutect2
- SLC29A2 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 133/792 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV100237067; called by muse, mutect2, varscan2
- SLCO1A2 | c.640G>T p.A214S | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs868190310; called by muse, mutect2, varscan2
- SLX4IP | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 98/636 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1204795379; called by muse, mutect2, varscan2
- SPATA31A7 | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 250/1510 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs1469634364; called by muse, mutect2, varscan2
- SPATA31D1 | c.4121C>T p.S1374F | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs1379878792; called by muse, mutect2, varscan2
- ST8SIA2 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 103/581 reads (18%) | PolyPhen benign (0.077); catalogued as rs752330245, COSV51568153; called by muse, mutect2, varscan2
- SYNCRIP | c.1694G>T p.R565L | Missense Mutation (SNP) | VAF 38/234 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV62288446; called by muse, mutect2, varscan2
- TULP4 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65577543; called by muse, mutect2, varscan2
- TXNDC11 | c.1130C>T p.A377V (on ENST00000356957 / NM_001303447.2; = p.A350V on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/614 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs370268157; called by muse, mutect2, varscan2
- WDFY3 | c.4519G>C p.V1507L | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs767214289; called by muse, mutect2, varscan2
- ZC3H14 | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 51/428 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.241); catalogued as COSV51773275; called by muse, mutect2, varscan2
- ZDBF2 | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100984917; called by muse, mutect2, varscan2
- ZIC3 | c.874C>A p.Q292K | Missense Mutation (SNP) | VAF 116/324 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as CM971600; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1208G>A p.R403K | Missense Mutation (SNP) | VAF 68/383 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV56272127; called by muse, mutect2, varscan2
- ZNF215 | c.580C>A p.L194M | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs762599532; called by muse, mutect2, varscan2
- ZNF333 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 67/461 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs772919054; called by muse, mutect2, varscan2
- ZNF418 | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | catalogued as rs773080623, COSV101268937; called by muse, varscan2
- ZNF419 | c.308A>C p.H103P | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs754316950; called by muse, mutect2, varscan2
- ZNF497 | c.1024G>A p.G342S | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1265562519; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.252A>T p.A84= | Splice Region (SNP) | VAF 30/206 reads (15%) | catalogued as COSV58673284; called by muse, varscan2
- ZNF804B | c.2006A>T p.H669L | Missense Mutation (SNP) | VAF 54/331 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.057); catalogued as COSV60838650; called by muse, mutect2, varscan2
- ZNF98 | c.694C>A p.H232N | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63337207; called by muse, mutect2, varscan2
- ABCB1 | c.3199G>T p.A1067S | Missense Mutation (SNP) | VAF 63/357 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ABCB5 | c.2093C>A p.A698D (on ENST00000404938 / NM_001163941.2; = p.A253D on NM_178559.6) | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ACSBG2 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 75/494 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACVR1C | c.1369A>T p.M457L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.084); called by muse, varscan2
- ACVR2B | c.1459G>C p.G487R | Missense Mutation (SNP) | VAF 94/731 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ADA2 | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAM21 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AL592490.1 | c.2613A>T p.Q871H | Missense Mutation (SNP) | VAF 54/417 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ALPK2 | c.4816A>T p.T1606S | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ANAPC5 | c.1535A>C p.Q512P | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, varscan2
- ANKRD30A | c.215A>T p.Q72L (on ENST00000611781; = p.Q16L on NM_052997.2) | Missense Mutation (SNP) | VAF 79/579 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKRD30BL | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 90/546 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD60 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 90/612 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANO3 | c.592-1G>T p.X198_splice | Splice Site (SNP) | VAF 32/161 reads (20%) | called by muse, varscan2
- APLNR | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 78/467 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- APLP1 | c.1843C>A p.H615N (on ENST00000221891 / NM_001024807.3; = p.H614N on NM_005166.4) | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP10 | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ARMC12 | c.729G>T p.Q243H (on ENST00000373866 / NM_001286574.2; = p.Q270H on NM_145028.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); called by muse, mutect2
- ASAH2 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 44/536 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASXL3 | c.1919G>T p.C640F | Missense Mutation (SNP) | VAF 60/339 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- BET1L | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 20/36 reads (56%) | called by mutect2, varscan2
- BMP6 | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 144/929 reads (16%) | called by muse, mutect2, varscan2
- BNC2 | c.1739G>T p.G580V | Missense Mutation (SNP) | VAF 50/445 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- BRINP1 | c.1636A>T p.M546L | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- BTC | c.278G>T p.C93F | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C12orf71 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- C16orf54 | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 84/535 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CATSPER2 | c.1271C>T p.S424F (on ENST00000321596 / NM_001282309.3; = p.S426F on NM_172095.4) | Missense Mutation (SNP) | VAF 99/735 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD93 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK19 | c.1053T>G p.I351M | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CDK5 | c.437G>C p.G146A | Missense Mutation (SNP) | VAF 73/556 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CENPJ | c.854A>G p.N285S | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHML | c.863A>T p.E288V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CKAP4 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 146/972 reads (15%) | called by muse, varscan2
- CLPB | c.1419+1G>T p.X473_splice | Splice Site (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2
- CLVS1 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 55/322 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- COL5A2 | c.3166G>T p.G1056C | Missense Mutation (SNP) | VAF 95/686 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.5288G>A p.G1763E (on ENST00000297405 / NM_001363185.1; = p.G1659E on NM_052900.3) | Missense Mutation (SNP) | VAF 64/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSMD3 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CSMD3 | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CTDP1 | c.671G>C p.R224P | Missense Mutation (SNP) | VAF 100/646 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DACT2 | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 86/468 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DEPTOR | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 49/277 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- DOCK9 | c.2508A>T p.K836N (on ENST00000376460 / NM_001366676.2; = p.K837N on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/296 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, varscan2
- DPY19L3 | c.1451A>T p.K484M | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.4230G>T p.Q1410H | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EIF4G3 | c.3519G>T p.M1173I | Missense Mutation (SNP) | VAF 130/786 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ELAVL2 | c.13C>A p.L5M | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); called by muse, varscan2
- ERBB4 | c.1278A>C p.R426S | Missense Mutation (SNP) | VAF 77/504 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F13B | c.775G>C p.G259R | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FABP4 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FAM207A | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 110/586 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- FAM83B | c.2584G>C p.D862H | Missense Mutation (SNP) | VAF 65/441 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- FAM9A | c.318dup p.A107Cfs*2 | Frame Shift Ins (INS) | VAF 84/238 reads (35%) | called by mutect2, varscan2
- FBN2 | c.2656A>T p.T886S | Missense Mutation (SNP) | VAF 97/502 reads (19%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO10 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FGFR2 | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 110/707 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.029); called by mutect2, varscan2
- FMO1 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 78/454 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- FOLH1 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.121); called by muse, varscan2
- FRAS1 | c.9464A>T p.Q3155L | Missense Mutation (SNP) | VAF 45/328 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, varscan2
- GALNT16 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GAPVD1 | c.1474A>T p.M492L | Missense Mutation (SNP) | VAF 38/313 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAS2 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GOLGA6L22 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 313/2150 reads (15%) | called by muse, varscan2
- GPR25 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GPR31 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 123/641 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GPR37L1 | c.370A>T p.T124S | Missense Mutation (SNP) | VAF 137/866 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- GPR87 | c.368C>A p.A123E | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GPX6 | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GRM6 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GSTCD | c.884A>G p.H295R (on ENST00000360505 / NM_001031720.3; = p.H208R on NM_024751.3) | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- HCN4 | c.3398G>A p.G1133E | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ2 | c.2427G>T p.E809D (on ENST00000467148 / NM_001037335.2; = p.E240D on NM_033405.3) | Missense Mutation (SNP) | VAF 62/377 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HERC2 | c.12973G>T p.G4325C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2
- HGF | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 119/660 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN2 | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 105/670 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- HS1BP3 | c.1093C>T p.Q365* | Nonsense Mutation (SNP) | VAF 110/725 reads (15%) | called by muse, mutect2, varscan2
- HYDIN | c.13174A>T p.I4392F | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- IFT140 | c.2135C>A p.P712H | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- IL36G | c.16G>T p.G6* | Nonsense Mutation (SNP) | VAF 79/585 reads (14%) | called by muse, mutect2, varscan2
- IQGAP2 | c.3942G>T p.Q1314H | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- KCNA6 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 68/321 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- KCNH2 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 127/834 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- KCNU1 | c.1027G>C p.D343H | Missense Mutation (SNP) | VAF 47/309 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- KIRREL1 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 34/204 reads (17%) | called by muse, mutect2, varscan2
- KPNB1 | c.1198A>T p.S400C | Missense Mutation (SNP) | VAF 60/344 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRTAP19-4 | c.148C>A p.R50S | Missense Mutation (SNP) | VAF 109/717 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LMNB1 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LMTK2 | c.1603G>C p.G535R | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- LRP1B | c.7742C>A p.S2581Y | Missense Mutation (SNP) | VAF 69/362 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 114/874 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC8D | c.538A>T p.S180C | Missense Mutation (SNP) | VAF 44/213 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRTM4 | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 87/626 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAPKBP1 | c.2571G>T p.W857C (on ENST00000456763 / NM_001128608.2; = p.W851C on NM_014994.3) | Missense Mutation (SNP) | VAF 121/648 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCIDAS | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- MFGE8 | c.1090del p.A364Lfs*9 | Frame Shift Del (DEL) | VAF 130/970 reads (13%) | called by mutect2, pindel, varscan2
- MYBPC1 | c.215-1G>T p.X72_splice (on ENST00000550270 / NM_206820.2; = p.X97_splice on NM_002465.4) | Splice Site (SNP) | VAF 78/448 reads (17%) | called by muse, mutect2, varscan2
- MYH13 | c.3759C>A p.C1253* | Nonsense Mutation (SNP) | VAF 57/341 reads (17%) | called by muse, mutect2, varscan2
- MYH4 | c.2226C>A p.S742R | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MYL7 | c.426+1G>T p.X142_splice | Splice Site (SNP) | VAF 46/270 reads (17%) | called by muse, mutect2, varscan2
- MYO19 | c.548-1G>T p.X183_splice | Splice Site (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- MYO9A | c.6976C>T p.Q2326* | Nonsense Mutation (SNP) | VAF 30/272 reads (11%) | called by muse, varscan2
- MYO9A | c.4327A>T p.K1443* | Nonsense Mutation (SNP) | VAF 57/344 reads (17%) | called by muse, mutect2, varscan2
- MYPOP | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- NACAD | c.2899C>A p.Q967K | Missense Mutation (SNP) | VAF 71/350 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, varscan2
- NOS3 | c.674+1G>T p.X225_splice | Splice Site (SNP) | VAF 55/403 reads (14%) | called by muse, mutect2, varscan2
- NRP1 | c.1480A>T p.I494F | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.72); PolyPhen benign (0.208); called by muse, mutect2
- NRXN3 | c.129G>T p.W43C | Missense Mutation (SNP) | VAF 101/559 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NRXN3 | c.1167A>T p.Q389H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- NXPH4 | c.740G>C p.R247P | Missense Mutation (SNP) | VAF 170/1029 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR2T34 | c.432G>C p.R144S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.142); called by mutect2, varscan2
- OR51I2 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52D1 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OR56A5 | c.65G>T p.S22I | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR7G2 | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 87/630 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- OVCH1 | c.2649T>A p.S883R | Missense Mutation (SNP) | VAF 72/527 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PBRM1 | c.4218C>A p.F1406L (on ENST00000296302 / NM_001366071.2; = p.F1354L on NM_018313.5) | Missense Mutation (SNP) | VAF 35/1002 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PBRM1 | c.4217T>A p.F1406Y (on ENST00000296302 / NM_001366071.2; = p.F1354Y on NM_018313.5) | Missense Mutation (SNP) | VAF 35/1006 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PCDH11X | c.911C>G p.A304G | Missense Mutation (SNP) | VAF 71/474 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, varscan2
- PCDH8 | c.493G>T p.G165C | Missense Mutation (SNP) | VAF 61/328 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE4A | c.1282G>T p.A428S (on ENST00000380702 / NM_001111307.2; = p.A189S on NM_006202.3) | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POM121L2 | c.2466T>A p.S822R | Missense Mutation (SNP) | VAF 108/565 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPP1R2B | c.160del p.A54Rfs*12 | Frame Shift Del (DEL) | VAF 247/1742 reads (14%) | called by mutect2, pindel, varscan2
- PRSS55 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 80/588 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB11FIP2 | c.1085G>T p.R362I | Missense Mutation (SNP) | VAF 59/291 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- RAD51AP2 | c.872G>T p.R291M | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- RELCH | c.3172G>T p.D1058Y | Missense Mutation (SNP) | VAF 56/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RFPL2 | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RHBDL1 | c.941G>A p.G314E (on ENST00000219551 / NM_001318733.2; = p.G249E on NM_001278720.2) | Missense Mutation (SNP) | VAF 24/614 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RHOD | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 68/429 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ROBO2 | c.2204C>G p.A735G | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ROR1 | c.2479G>T p.G827* | Nonsense Mutation (SNP) | VAF 63/446 reads (14%) | called by muse, mutect2, varscan2
- RPL37A | c.133-5T>C | Splice Region (SNP) | VAF 57/388 reads (15%) | called by muse, mutect2, varscan2
- RYR1 | c.7579C>A p.L2527M | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.13213C>G p.L4405V | Missense Mutation (SNP) | VAF 110/809 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SALL3 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 72/303 reads (24%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- SAMSN1 | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SAMSN1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 25/179 reads (14%) | called by muse, mutect2, varscan2
- SCN5A | c.2933G>T p.W978L | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SDK1 | c.3319G>T p.G1107W | Missense Mutation (SNP) | VAF 41/231 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC16B | c.2498G>A p.G833D | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- SEMA3F | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 98/759 reads (13%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.749C>A p.T250K | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.137); called by mutect2, varscan2
- SETBP1 | c.643A>T p.S215C | Missense Mutation (SNP) | VAF 96/618 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- SLC17A7 | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC39A12 | c.926C>A p.T309N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- SLITRK1 | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 62/342 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SNX8 | c.1028A>T p.Q343L | Missense Mutation (SNP) | VAF 106/586 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31A6 | c.674C>A p.T225N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by mutect2, varscan2
- SPATS1 | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, varscan2
- SPATS1 | c.677C>A p.P226Q | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, varscan2
- SPIRE1 | c.998T>C p.L333S | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTA1 | c.3463G>T p.A1155S | Missense Mutation (SNP) | VAF 47/338 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPTB | c.3393G>T p.Q1131H | Missense Mutation (SNP) | VAF 131/706 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- SPTBN4 | c.1516G>T p.V506L | Missense Mutation (SNP) | VAF 96/624 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- SRGAP1 | c.913G>C p.A305P | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SSTR1 | c.1152C>A p.C384* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- ST7 | c.1498+1G>C p.X500_splice (on ENST00000265437 / NM_021908.3; = p.X477_splice on NM_018412.4) | Splice Site (SNP) | VAF 60/382 reads (16%) | called by muse, varscan2
- STK31 | c.1817A>G p.Y606C | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, varscan2
- SYNPO | c.1055G>T p.S352I (on ENST00000394243 / NM_001166208.2; = p.S108I on NM_007286.6) | Missense Mutation (SNP) | VAF 292/1452 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- TANC2 | c.4168C>A p.Q1390K | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEK | c.2790T>A p.N930K | Missense Mutation (SNP) | VAF 96/715 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TGM6 | c.584A>T p.D195V | Missense Mutation (SNP) | VAF 151/815 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TGM6 | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 148/978 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TMA16 | c.514A>C p.K172Q | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TMCO4 | c.1719G>T p.L573F | Missense Mutation (SNP) | VAF 114/804 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.02); called by muse, varscan2
- TMEM119 | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 92/601 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TMEM185B | c.1003G>T p.G335W | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TMPRSS11B | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 80/465 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TNNT2 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 180/1134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TP53BP1 | c.778G>T p.E260* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2
- TRBV23-1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- TRIM55 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 65/349 reads (19%) | called by muse, mutect2, varscan2
- TRIM63 | c.1031C>A p.S344Y | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TRIM64B | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 62/972 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, mutect2
- TRIM68 | c.1073A>T p.H358L | Missense Mutation (SNP) | VAF 44/283 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TRIP11 | c.4741C>G p.L1581V | Missense Mutation (SNP) | VAF 71/495 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TRMT9B | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC14 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTN | c.28722G>C p.Q9574H (on ENST00000591111; = p.Q8647H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/150 reads (13%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UBE4B | c.2540del p.Y847Lfs*19 (on ENST00000343090 / NM_001105562.3; = p.Y718Lfs*19 on NM_006048.5) | Frame Shift Del (DEL) | VAF 41/327 reads (13%) | called by mutect2, pindel, varscan2
- UGT2A3 | c.1421T>A p.L474Q | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- UNC5C | c.2152G>C p.E718Q | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- UNC80 | c.6655G>T p.V2219L | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP36 | c.538A>T p.N180Y | Missense Mutation (SNP) | VAF 85/599 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WNT11 | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XYLB | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 46/283 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZBTB4 | c.917A>T p.H306L | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZKSCAN7 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 38/374 reads (10%) | called by muse, mutect2, varscan2
- ZNF138 | c.548C>G p.T183S (on ENST00000307355 / NM_001367572.1; = p.T157S on NM_006524.4) | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- ZNF142 | c.4286C>G p.P1429R (on ENST00000411696 / NM_001379660.1; = p.P1229R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/807 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF407 | c.436A>G p.K146E | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF423 | c.401G>T p.G134V (on ENST00000563137 / NM_001379286.1; = p.G126V on NM_015069.4) | Missense Mutation (SNP) | VAF 74/463 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF615 | c.653A>T p.Q218L | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF716 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- ZNF729 | c.2008G>T p.A670S | Missense Mutation (SNP) | VAF 85/540 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0.013); called by muse, varscan2
- ZNF736 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ZNF800 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- ZNF831 | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZXDA | c.1651A>T p.N551Y | Missense Mutation (SNP) | VAF 106/480 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTN2 | c.2613C>A p.G871= | Silent (SNP) | VAF 83/512 reads (16%) | called by muse, mutect2, varscan2
- ADD1 | c.735G>T p.G245= | Silent (SNP) | VAF 58/326 reads (18%) | catalogued as rs1204328814, COSV99296254; called by muse, mutect2, varscan2
- ADGRE2 | c.1365C>T p.N455= | Silent (SNP) | VAF 51/456 reads (11%) | catalogued as rs773851169, COSV59695498; called by muse, mutect2, varscan2
- AMOTL1 | c.813G>A p.E271= | Silent (SNP) | VAF 42/292 reads (14%) | called by muse, mutect2, varscan2
- APAF1 | c.2688A>T p.S896= (on ENST00000551964 / NM_181861.2; = p.S842= on NM_001160.3) | Silent (SNP) | VAF 116/754 reads (15%) | called by muse, mutect2, varscan2
- APOB | c.12831A>G p.S4277= | Silent (SNP) | VAF 52/344 reads (15%) | catalogued as COSV99267899; called by muse, mutect2, varscan2
- ARHGAP15 | c.1077C>T p.F359= | Silent (SNP) | VAF 58/409 reads (14%) | called by muse, mutect2, varscan2
- CACNA1E | c.4017C>T p.N1339= | Silent (SNP) | VAF 42/233 reads (18%) | called by muse, varscan2
- CALR | c.354C>T p.D118= | Silent (SNP) | VAF 29/822 reads (4%) | called by muse, mutect2
- CEACAM21 | c.501C>T p.H167= | Silent (SNP) | VAF 78/483 reads (16%) | catalogued as rs781887854; called by muse, mutect2, varscan2
- CES1 | c.597C>A p.R199= | Silent (SNP) | VAF 70/780 reads (9%) | called by muse, mutect2
- CGB1 | c.432C>A p.P144= | Silent (SNP) | VAF 64/394 reads (16%) | called by muse, mutect2, varscan2
- CLSTN2 | c.1308C>A p.T436= | Silent (SNP) | VAF 68/484 reads (14%) | catalogued as rs778581462; called by muse, mutect2, varscan2
- DCHS1 | c.198G>T p.A66= | Silent (SNP) | VAF 62/320 reads (19%) | catalogued as rs748110740; called by muse, varscan2
- DCSTAMP | c.879G>T p.L293= | Silent (SNP) | VAF 49/394 reads (12%) | called by muse, mutect2, varscan2
- DLD | c.1215A>T p.S405= | Silent (SNP) | VAF 93/635 reads (15%) | called by muse, mutect2, varscan2
- DLL1 | c.1914G>T p.A638= | Silent (SNP) | VAF 132/559 reads (24%) | catalogued as COSV64537280; called by muse, mutect2, varscan2
- DSCAML1 | c.2103G>T p.S701= (on ENST00000321322; = p.S641= on NM_020693.4) | Silent (SNP) | VAF 126/913 reads (14%) | called by muse, mutect2, varscan2
- ERBB4 | c.2289G>T p.V763= | Silent (SNP) | VAF 58/449 reads (13%) | called by muse, mutect2, varscan2
- EXTL1 | c.192C>A p.L64= | Silent (SNP) | VAF 30/282 reads (11%) | called by muse, mutect2, varscan2
- FBN3 | c.459C>A p.R153= | Silent (SNP) | VAF 64/382 reads (17%) | called by muse, mutect2, varscan2
- FCN1 | c.171C>A p.P57= | Silent (SNP) | VAF 106/658 reads (16%) | catalogued as COSV100878989; called by muse, mutect2, varscan2
- FERMT2 | c.1023A>G p.K341= | Silent (SNP) | VAF 52/357 reads (15%) | called by muse, mutect2, varscan2
- FGF6 | c.447A>T p.A149= | Silent (SNP) | VAF 49/212 reads (23%) | called by muse, mutect2, varscan2
- G6PC2 | c.900A>G p.S300= | Silent (SNP) | VAF 130/800 reads (16%) | called by muse, mutect2, varscan2
- H2BW2 | c.150C>T p.N50= | Silent (SNP) | VAF 63/146 reads (43%) | called by muse, mutect2, varscan2
- HMCN1 | c.9126C>G p.G3042= | Silent (SNP) | VAF 76/540 reads (14%) | catalogued as COSV54928978; called by muse, varscan2
- HPX | c.522G>T p.T174= | Silent (SNP) | VAF 81/422 reads (19%) | catalogued as COSV99793381; called by muse, mutect2, varscan2
- IL36G | c.15A>T p.P5= | Silent (SNP) | VAF 76/579 reads (13%) | called by muse, mutect2, varscan2
- INPPL1 | c.927G>T p.V309= | Silent (SNP) | VAF 124/729 reads (17%) | catalogued as COSV99995812; called by muse, mutect2, varscan2
- ITGAD | c.423G>T p.T141= | Silent (SNP) | VAF 30/158 reads (19%) | called by muse, mutect2, varscan2
- KCNJ3 | c.1446T>A p.A482= | Silent (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- KRTAP12-3 | c.276C>A p.T92= | Silent (SNP) | VAF 26/165 reads (16%) | called by muse, mutect2, varscan2
- LHX6 | c.778C>A p.R260= (on ENST00000373755 / NM_001242334.2; = p.R289= on NM_014368.5) | Silent (SNP) | VAF 109/704 reads (15%) | catalogued as rs973461054; called by muse, mutect2, varscan2
- LRP6 | c.4344C>T p.S1448= | Silent (SNP) | VAF 57/341 reads (17%) | catalogued as rs148272212; called by muse, mutect2, varscan2
- MAGEB10 | c.393C>A p.P131= | Silent (SNP) | VAF 66/238 reads (28%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1854C>A p.S618= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV58477159; called by muse, mutect2, varscan2
- MMEL1 | c.184C>T p.L62= | Silent (SNP) | VAF 99/710 reads (14%) | catalogued as rs150544037; called by muse, mutect2, varscan2
- MUC5B | c.11889C>G p.P3963= | Silent (SNP) | VAF 184/1297 reads (14%) | called by muse, mutect2, varscan2
- MYO7A | c.633C>T p.S211= | Silent (SNP) | VAF 72/571 reads (13%) | called by muse, mutect2, varscan2
- NPIPB2 | c.924T>A p.L308= (on ENST00000399147; = p.L168= on NM_001355514.1) | Silent (SNP) | VAF 137/1380 reads (10%) | called by muse, mutect2, varscan2
- ONECUT2 | c.1125A>G p.P375= | Silent (SNP) | VAF 152/1035 reads (15%) | catalogued as COSV72203496; called by muse, mutect2, varscan2
- OR10G8 | c.546C>A p.P182= | Silent (SNP) | VAF 59/304 reads (19%) | catalogued as COSV101461864; called by muse, mutect2, varscan2
- OR10Q1 | c.177C>A p.L59= | Silent (SNP) | VAF 79/529 reads (15%) | called by muse, mutect2, varscan2
- OR4C46 | c.654C>A p.V218= | Silent (SNP) | VAF 76/565 reads (13%) | catalogued as rs769201663, COSV60220779; called by muse, mutect2, varscan2
- OR7A10 | c.192C>T p.S64= | Silent (SNP) | VAF 64/392 reads (16%) | catalogued as rs753513301, COSV99932535; called by muse, mutect2, varscan2
- OR7G3 | c.414C>A p.P138= | Silent (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- P3H3 | c.1980C>A p.A660= | Silent (SNP) | VAF 35/217 reads (16%) | called by muse, mutect2, varscan2
- PCDHA2 | c.2196C>T p.R732= | Silent (SNP) | VAF 130/784 reads (17%) | catalogued as COSV65367714; called by muse, mutect2, varscan2
- PCDHA8 | c.1218G>A p.S406= | Silent (SNP) | VAF 112/700 reads (16%) | catalogued as rs182995378; called by muse, mutect2, varscan2
- PCDHGA5 | c.1017C>T p.D339= | Silent (SNP) | VAF 51/287 reads (18%) | catalogued as rs762446364, COSV53914541; called by muse, mutect2, varscan2
- PCSK1 | c.1960C>A p.R654= | Silent (SNP) | VAF 28/180 reads (16%) | catalogued as COSV60734915; called by muse, mutect2, varscan2
- PDZRN3 | c.2850C>A p.I950= | Silent (SNP) | VAF 78/463 reads (17%) | catalogued as rs1335511126; called by muse, mutect2, varscan2
- PDZRN4 | c.2370G>T p.S790= (on ENST00000402685 / NM_001164595.2; = p.S532= on NM_013377.4) | Silent (SNP) | VAF 89/578 reads (15%) | catalogued as COSV54191470; called by muse, mutect2, varscan2
- PLEC | c.10167G>C p.T3389= (on ENST00000322810 / NM_201380.4; = p.T3279= on NM_000445.5) | Silent (SNP) | VAF 191/1119 reads (17%) | catalogued as COSV59604436; called by muse, mutect2, varscan2
- POU2F2 | c.1110G>A p.P370= (on ENST00000526816 / NM_001207025.3; = p.P354= on NM_002698.5) | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as COSV60760096; called by muse, mutect2
- POU6F2 | c.1389C>A p.G463= | Silent (SNP) | VAF 44/277 reads (16%) | called by muse, varscan2
- PRDM8 | c.846C>T p.S282= | Silent (SNP) | VAF 86/536 reads (16%) | called by muse, mutect2, varscan2
- PRKCG | c.708G>T p.V236= | Silent (SNP) | VAF 99/636 reads (16%) | catalogued as COSV54731664; called by muse, mutect2, varscan2
- PTK2 | c.552G>T p.R184= | Silent (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- RAD51AP2 | c.2625A>T p.S875= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as COSV67587510; called by muse, mutect2, varscan2
- RELN | c.6037C>T p.L2013= | Silent (SNP) | VAF 87/509 reads (17%) | called by muse, mutect2, varscan2
- RHBDD1 | c.741G>T p.P247= | Silent (SNP) | VAF 68/316 reads (22%) | catalogued as rs373351039; called by muse, mutect2, varscan2
- SH2B1 | c.2061G>C p.G687= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- SIAH3 | c.375C>G p.P125= | Silent (SNP) | VAF 75/400 reads (19%) | catalogued as COSV101247756; called by muse, mutect2, varscan2
- SLC12A4 | c.834G>T p.S278= | Silent (SNP) | VAF 145/1056 reads (14%) | called by muse, varscan2
- SLC39A11 | c.39G>T p.L13= | Silent (SNP) | VAF 67/565 reads (12%) | called by muse, mutect2, varscan2
- SMO | c.871C>A p.R291= | Silent (SNP) | VAF 83/468 reads (18%) | catalogued as COSV50827516; called by muse, mutect2, varscan2
- SMOC1 | c.840G>C p.L280= | Silent (SNP) | VAF 91/642 reads (14%) | called by muse, mutect2, varscan2
- TCF3 | c.1734G>A p.L578= | Silent (SNP) | VAF 55/361 reads (15%) | called by muse, mutect2, varscan2
- TJP3 | c.1965C>G p.P655= | Silent (SNP) | VAF 75/462 reads (16%) | called by muse, mutect2, varscan2
- TLR2 | c.669C>T p.S223= | Silent (SNP) | VAF 34/248 reads (14%) | catalogued as rs776817219, COSV52604868; called by muse, mutect2, varscan2
- TMEFF1 | c.549A>G p.A183= | Silent (SNP) | VAF 36/240 reads (15%) | called by muse, mutect2, varscan2
- WDR3 | c.42G>T p.A14= | Silent (SNP) | VAF 74/396 reads (19%) | called by muse, mutect2, varscan2
- WRAP73 | c.102G>A p.R34= | Silent (SNP) | VAF 38/227 reads (17%) | called by muse, mutect2, varscan2
- ZEB2 | c.2151C>A p.P717= | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- ZIC5 | c.828G>A p.P276= | Silent (SNP) | VAF 17/83 reads (20%) | called by muse, mutect2, varscan2
- ZIC5 | c.528G>T p.S176= | Silent (SNP) | VAF 60/324 reads (19%) | called by muse, mutect2, varscan2
- ZNF322 | c.1149G>T p.V383= | Silent (SNP) | VAF 98/1198 reads (8%) | called by muse, mutect2
- ZNF536 | c.3099C>T p.N1033= | Silent (SNP) | VAF 67/534 reads (13%) | catalogued as COSV100835752; called by muse, mutect2, varscan2
- ZNF548 | c.393C>A p.S131= | Silent (SNP) | VAF 44/389 reads (11%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+7098C>A | Intron (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- AC136628.2 | n.839C>A | RNA (SNP) | VAF 93/725 reads (13%) | called by muse, mutect2, varscan2
- AC136628.2 | n.840A>T | RNA (SNP) | VAF 94/724 reads (13%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3101+869G>A | Intron (SNP) | VAF 4/52 reads (8%) | catalogued as COSV54663528, COSV99589403; called by muse, mutect2
- AP000769.5 | chr11:65498232 del A | 5'Flank (DEL) | VAF 41/423 reads (10%) | called by mutect2, pindel, varscan2
- ARPC5 | c.216+35G>T | Intron (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- BTK | c.392-49G>T | Intron (SNP) | VAF 75/190 reads (39%) | called by muse, mutect2, varscan2
- CDH6 | c.1882+57T>A | Intron (SNP) | VAF 43/150 reads (29%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811894 G>T | 3'Flank (SNP) | VAF 101/550 reads (18%) | called by muse, mutect2, varscan2
- CLK2P1 | n.1006G>C | RNA (SNP) | VAF 129/841 reads (15%) | called by muse, mutect2, varscan2
- COL1A2 | c.2674-51A>T | Intron (SNP) | VAF 77/287 reads (27%) | catalogued as COSV51955079; called by muse, mutect2, varscan2
- COP1 | c.*2G>T | 3'UTR (SNP) | VAF 33/253 reads (13%) | catalogued as rs758966237; called by muse, mutect2, varscan2
- CSHL1 | c.10+43G>T | Intron (SNP) | VAF 47/355 reads (13%) | catalogued as rs772785939, COSV51987676; called by muse, mutect2, varscan2
- CTDP1 | chr18:79679469 C>A | 5'Flank (SNP) | VAF 102/688 reads (15%) | called by muse, varscan2
- CTDP1 | chr18:79679534 T>C | 5'Flank (SNP) | VAF 108/729 reads (15%) | called by muse, varscan2
- DCHS2 | n.4694C>G | RNA (SNP) | VAF 30/220 reads (14%) | called by muse, mutect2, varscan2
- DDX11 | c.1876-14G>A | Intron (SNP) | VAF 21/357 reads (6%) | called by muse, mutect2
- DHODH | c.*18A>G | 3'UTR (SNP) | VAF 54/804 reads (7%) | called by muse, mutect2
- EDN3 | c.52+10C>A | Intron (SNP) | VAF 85/501 reads (17%) | called by muse, mutect2, varscan2
- FAM53C | chr5:138338249 G>A | 5'Flank (SNP) | VAF 93/572 reads (16%) | catalogued as rs1478173709; called by muse, mutect2, varscan2
- FOLR2 | c.-25+425G>A | Intron (SNP) | VAF 48/302 reads (16%) | called by muse, mutect2, varscan2
- GGNBP1 | n.778C>T | RNA (SNP) | VAF 60/616 reads (10%) | catalogued as rs376146249; called by muse, mutect2
- GRM1 | c.*2G>A | 3'UTR (SNP) | VAF 164/691 reads (24%) | called by muse, mutect2, varscan2
- IGFALS | chr16:1793710 G>A | 5'Flank (SNP) | VAF 23/192 reads (12%) | called by muse, mutect2, varscan2
- KDM5D | c.4070-57G>C | Intron (SNP) | VAF 108/308 reads (35%) | called by muse, mutect2, varscan2
- LCP2 | c.-2C>T | 5'UTR (SNP) | VAF 48/233 reads (21%) | catalogued as rs749671423; called by muse, mutect2, varscan2
- LINC01591 | n.568A>C | RNA (SNP) | VAF 22/140 reads (16%) | called by mutect2, varscan2
- LINC02118 | n.209G>T | RNA (SNP) | VAF 30/247 reads (12%) | catalogued as rs894275071; called by muse, mutect2, varscan2
- LIPH | c.49+5474G>T | Intron (SNP) | VAF 20/131 reads (15%) | called by muse, varscan2
- MASP1 | c.1304-5521T>A | Intron (SNP) | VAF 24/120 reads (20%) | called by muse, mutect2, varscan2
- MDGA2 | c.1525+1918A>T | Intron (SNP) | VAF 25/182 reads (14%) | called by muse, varscan2
- MGAM | c.4619-2025T>A | Intron (SNP) | VAF 96/477 reads (20%) | called by muse, varscan2
- MIR516A1 | n.7G>T | RNA (SNP) | VAF 41/260 reads (16%) | called by muse, varscan2
- MIR520E | n.18C>A | RNA (SNP) | VAF 52/414 reads (13%) | called by muse, varscan2
- MIR663B | n.71C>A | RNA (SNP) | VAF 37/203 reads (18%) | catalogued as rs749966310; called by muse, mutect2, varscan2
- NDUFA5 | c.184-1133A>G | Intron (SNP) | VAF 44/265 reads (17%) | called by muse, varscan2
- NDUFA5 | c.-11T>A | 5'UTR (SNP) | VAF 116/667 reads (17%) | called by muse, mutect2, varscan2
- NEK7 | c.198+3163G>T | Intron (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- NGEF | c.-155C>A | 5'UTR (SNP) | VAF 91/471 reads (19%) | called by muse, mutect2, varscan2
- NLRP2 | c.2708+50C>A | Intron (SNP) | VAF 58/429 reads (14%) | called by muse, mutect2, varscan2
- OR3A4P | n.952G>T | RNA (SNP) | VAF 105/601 reads (17%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.1237-520A>G | Intron (SNP) | VAF 93/557 reads (17%) | called by muse, mutect2, varscan2
- PLOD2 | c.109+34G>T | Intron (SNP) | VAF 59/342 reads (17%) | called by muse, mutect2, varscan2
- RASGEF1B | c.438+56G>T | Intron (SNP) | VAF 86/565 reads (15%) | called by muse, mutect2, varscan2
- RBFOX1 | c.996-15725G>A | Intron (SNP) | VAF 51/389 reads (13%) | catalogued as rs550037838, COSV100299521, COSV60958818; called by muse, mutect2, varscan2
- RCAN1 | c.586+86T>C | Intron (SNP) | VAF 15/118 reads (13%) | called by muse, mutect2, varscan2
- SCARB2 | c.424-27C>T | Intron (SNP) | VAF 89/608 reads (15%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3775G>T | RNA (SNP) | VAF 18/172 reads (10%) | called by mutect2, varscan2
- SPANXN1 | c.-52dup | 5'UTR (INS) | VAF 67/268 reads (25%) | called by mutect2, pindel, varscan2
- TGIF1 | chr18:3447683 G>T | 5'Flank (SNP) | VAF 22/782 reads (3%) | called by muse, mutect2
- TMCO1 | c.*2218A>G | 3'UTR (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- TRIM67 | chr1:231162960 C>A | 5'Flank (SNP) | VAF 79/478 reads (17%) | catalogued as rs779929803; called by muse, mutect2, varscan2
- TTBK1 | c.1986+6353G>T | Intron (SNP) | VAF 112/768 reads (15%) | called by muse, mutect2, varscan2
- VAPB | c.*4892A>G | 3'UTR (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
